Somatic mutation profile of tumor specimen TCGA-CS-6667-01A (aliquot TCGA-CS-6667-01A-12D-2024-08) from TCGA case TCGA-CS-6667, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 39.4 years (14,375 days).
Specimen TCGA-CS-6667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ca65fcd-79e0-4944-a25c-e1e220cf99e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6667-10A (Blood Derived Normal), aliquot TCGA-CS-6667-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd9290b0-5af7-4d12-94df-ef0a9cc70ed0

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Translation Start Site 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ABCA12 | c.5942T>C p.I1981T (on ENST00000272895 / NM_173076.3; = p.I1663T on NM_015657.3) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV55961330; called by muse, mutect2, varscan2
- CASQ2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV54770980; called by muse, mutect2, varscan2
- DCAF8L1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV71595327; called by muse, mutect2, varscan2
- EPHA5 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as COSV56648490; called by muse, mutect2, varscan2
- FAT4 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67888246; called by muse, mutect2, varscan2
- FREM2 | c.9013C>G p.L3005V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs148812741; called by muse, mutect2, varscan2
- GEMIN5 | c.4166A>G p.Q1389R | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs763445158, COSV53561094; called by muse, mutect2, varscan2
- GRM4 | c.2527T>G p.Y843D | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV65214199; called by muse, mutect2, varscan2
- KCND1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as rs782043855, COSV54414352; called by muse, mutect2, varscan2
- POLA1 | c.1861T>A p.F621I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV66886853; called by muse, mutect2, varscan2
- ROBO3 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67300868, COSV67302683; called by muse, mutect2
- TASOR | c.1220C>T p.P407L (on ENST00000355628 / NM_001365636.2; = p.P11L on NM_015224.3) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62928065; called by muse, mutect2, varscan2
- TMX1 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV63284859, COSV63284869; called by muse, mutect2, varscan2
- WDR62 | c.1355A>T p.K452I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54335554; called by muse, mutect2, varscan2
- WWC3 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.428); catalogued as rs759501029, COSV66503879; called by muse, mutect2, varscan2
- ASAH2 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOF | c.2711G>C p.G904A | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2
- VPS13C | c.906_921del p.A303Ifs*17 (on ENST00000644861 / NM_020821.3; = p.A260Ifs*17 on NM_017684.5) | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1023C>T p.C341= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs375597036; called by muse, mutect2, varscan2
- IL17REL | c.924C>T p.S308= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV58008318; called by muse, mutect2, varscan2
- OPCML | c.336G>A p.P112= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs369569350; called by muse, mutect2, varscan2
- RAG2 | c.1473C>T p.P491= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV57557909; called by muse, mutect2, varscan2
- RARRES2 | c.276T>C p.N92= | Silent (SNP) | VAF 230/604 reads (38%) | catalogued as rs1234031725, COSV56231451; called by muse, mutect2, varscan2
- ZNF157 | c.777A>C p.A259= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65658460, COSV65659029; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23287G>A | Intron (SNP) | VAF 81/256 reads (32%) | catalogued as rs370175895, COSV59380792; called by muse, mutect2, varscan2
